Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A620, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A620-01A (Primary Tumor).

Gross Description: There is a fragment of the tongue tissue up to 7 x 4.5 cm in size with an ulcer-like gray-pink tumor up to 4.5 cm in its diameter, 0.8 cm thick. Tumor is predominantly localized near the base of the tongue.

Microscopic Description: Squamous cell carcinoma, keratinizing sub-type, G-1, with ulceration. Four examined I level lymph nodes demonstrated reactive follicular hyperplasia, sinus histiocytosis. Four examined II level lymph nodes demonstrated reactive follicular hyperplasia, lipomatosis. Four III level lymph nodes were examined. One of them demonstrated metastasis of the squamous cell carcinoma.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Localized, NOS, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: Oral cavity tumor checklist

Histological type: Squamous cell carcinoma, keratinizing subtype of the oral cavity

Tumor location: Oral cavity, tongue, base

Tumor size: 0.8 x 4.5 cm

Tumor features: Ulcerated

Venous invasion: Absent

Margins: Uninvolved

Tumor grade: Well differentiated

Diagnosis details: None

Comments: None

ICD-O-3
Carcinoma, squamous cell,
Keratinizing NOS 807113
Site: Base of tongue
CO1.9
JAW 4/12/13

ctDNA Discrepancy		☒

Source: NCI Genomic Data Commons file a46e89b2-382d-4cd6-978a-ea5bd411cd29 (TCGA-F7-A620.4AB2C9FF-340D-446B-8A0A-F9A4DBBFECF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).